Somatic mutation profile of tumor specimen TCGA-E8-A432-01A (aliquot TCGA-E8-A432-01A-11D-A23M-08) from TCGA case TCGA-E8-A432, project TCGA-THCA (Thyroid Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Papillary adenocarcinoma, NOS; Tissue or organ of origin: Thyroid gland; AJCC pathologic stage: Stage II; Age at diagnosis: 57.1 years (20,874 days).
Specimen TCGA-E8-A432-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 4df6ff81-2702-49bc-b4d2-94127cde3da6.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-E8-A432-10A (Blood Derived Normal), aliquot TCGA-E8-A432-10A-01D-A23K-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/374aaf6b-6435-4b5f-b32f-001c3255829a

The open-access MAF lists 26 somatic variants for this specimen: 19 protein-altering or splice-affecting, 5 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 13, Silent 5, Frame Shift Del 3, Nonsense Mutation 2, In Frame Del 1, 3'Flank 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ALPK3 | c.664C>T p.Q222* | Nonsense Mutation (SNP) | VAF 7/33 reads (21%) | catalogued as COSV99361576; called by muse, mutect2, varscan2
- BTN3A3 | c.1131A>T p.R377S | Missense Mutation (SNP) | VAF 12/70 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99764985; called by muse, mutect2, varscan2
- DOCK7 | c.1997C>T p.P666L | Missense Mutation (SNP) | VAF 5/34 reads (15%) | SIFT tolerated (1); PolyPhen probably damaging (1); catalogued as COSV99225383; called by muse, mutect2, varscan2
- KMT2D | c.2132C>T p.P711L | Missense Mutation (SNP) | VAF 19/108 reads (18%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.215); catalogued as rs893615522, COSV99984340; called by muse, mutect2, varscan2
- LNPEP | c.2521A>G p.K841E | Missense Mutation (SNP) | VAF 12/37 reads (32%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV99183575; called by muse, mutect2, varscan2
- MTERF1 | c.796A>G p.N266D | Missense Mutation (SNP) | VAF 5/46 reads (11%) | SIFT tolerated (0.33); PolyPhen benign (0); catalogued as COSV100699584; called by muse, mutect2, varscan2
- OR5D13 | c.761A>G p.H254R | Missense Mutation (SNP) | VAF 24/80 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as rs1305477003, COSV100686966; called by muse, mutect2, varscan2
- PDZD2 | c.805G>A p.G269S | Missense Mutation (SNP) | VAF 24/82 reads (29%) | SIFT tolerated (0.08); PolyPhen benign (0.15); catalogued as COSV56869466; called by muse, mutect2, varscan2
- PIK3R5 | c.1665G>T p.Q555H | Missense Mutation (SNP) | VAF 3/17 reads (18%) | SIFT deleterious (0.05); PolyPhen benign (0.121); catalogued as COSV99353670; called by muse, mutect2
- PLCH1 | c.196A>T p.I66F (on ENST00000340059 / NM_001130960.2; = p.I78F on NM_014996.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 18/52 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV100397711; called by muse, mutect2, varscan2
- SLC22A6 | c.1416C>G p.S472R | Missense Mutation (SNP) | VAF 7/43 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV100842883, COSV100842908; called by muse, mutect2, varscan2
- TTN | c.97072T>A p.W32358R (on ENST00000591111; = p.W24934R on NM_003319.4) | Missense Mutation (SNP) | VAF 17/76 reads (22%) | PolyPhen probably damaging (0.999); catalogued as COSV100622569; called by muse, mutect2, varscan2
- ZC3H13 | c.1936C>T p.R646* | Nonsense Mutation (SNP) | VAF 13/42 reads (31%) | catalogued as COSV54458109; called by muse, mutect2, varscan2
- ZNF76 | c.361G>T p.D121Y | Missense Mutation (SNP) | VAF 7/32 reads (22%) | SIFT tolerated (0.06); PolyPhen benign (0.425); catalogued as COSV99987814; called by muse, mutect2
- ADGRB3 | c.1429del p.R477Gfs*3 | Frame Shift Del (DEL) | VAF 20/117 reads (17%) | called by mutect2, pindel, varscan2
- KAT5 | c.940del p.Q314Rfs*28 | Frame Shift Del (DEL) | VAF 21/87 reads (24%) | called by mutect2, pindel, varscan2
- SLC35D3 | c.694T>C p.C232R | Missense Mutation (SNP) | VAF 3/42 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.977); called by muse, mutect2
- SLC35G2 | c.842_844del p.K281del | In Frame Del (DEL) | VAF 24/137 reads (18%) | called by pindel, varscan2
- TTLL5 | c.872_897del p.G291Afs*2 | Frame Shift Del (DEL) | VAF 12/56 reads (21%) | called by mutect2, pindel
- ARSK | c.117C>T p.S39= | Silent (SNP) | VAF 6/30 reads (20%) | catalogued as COSV100706766; called by muse, varscan2
- C1orf53 | c.195G>A p.R65= | Silent (SNP) | VAF 6/16 reads (38%) | catalogued as rs770857547, COSV100956478; called by muse, varscan2
- NPAP1 | c.327A>G p.G109= | Silent (SNP) | VAF 9/68 reads (13%) | catalogued as rs1466137444, COSV100275772; called by muse, mutect2, varscan2
- PCDHA8 | c.1086C>T p.D362= | Silent (SNP) | VAF 49/186 reads (26%) | catalogued as COSV65339088; called by muse, mutect2, varscan2
- POU2AF1 | c.423C>T p.T141= | Silent (SNP) | VAF 12/64 reads (19%) | catalogued as COSV101260685; called by muse, mutect2, varscan2
- AP000769.3 | chr11:65505483 C>T | 5'Flank (SNP) | VAF 14/88 reads (16%) | catalogued as rs764430945; called by muse, mutect2, varscan2
- Vault | chr5:136080495 A>G | 3'Flank (SNP) | VAF 24/75 reads (32%) | catalogued as rs758003078; called by muse, mutect2, varscan2
